Somatic mutation profile of tumor specimen TCGA-D3-A2JB-06A (aliquot TCGA-D3-A2JB-06A-11D-A196-08) from TCGA case TCGA-D3-A2JB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.9 years (28,819 days).
Specimen TCGA-D3-A2JB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6f76140-5194-42ba-941f-5db90a8fe775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JB-10A (Blood Derived Normal), aliquot TCGA-D3-A2JB-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f5b9efe-b1ec-45bf-bed2-5179dc4d9d85

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 12.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP298-TCP10L | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.255); catalogued as COSV51593125; called by muse, mutect2, varscan2
- CMTR1 | c.2256G>T p.R752S | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64982719; called by muse, mutect2, varscan2
- DGAT2 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV57176971; called by muse, mutect2, varscan2
- ERC1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs886848143, COSV61695255; called by mutect2, varscan2
- HNRNPH2 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54510151; called by mutect2, varscan2
- KDM5B | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV52510844; called by muse, varscan2
- KDM6B | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs575929747, COSV99640699; called by muse, mutect2, varscan2
- L1CAM | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV62829377; called by muse, mutect2, varscan2
- PARP2 | c.285C>G p.D95E | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51638231, COSV51641033; called by muse, mutect2
- SLC39A9 | c.628C>G p.H210D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV50363227; called by muse, mutect2, varscan2
- THBD | c.1302C>A p.D434E | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV65702953; called by muse, mutect2, varscan2
- TMEM147 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV52870384; called by mutect2, varscan2
